Somatic mutation profile of tumor specimen ALCH-B1LU-TTP1-A (aliquot ALCH-B1LU-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1LU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 79.8 years (29,140 days).
Specimen ALCH-B1LU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd5b26e5-bb69-41ab-931b-44696d9890cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LU-NB1-A (Blood Derived Normal), aliquot ALCH-B1LU-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93de6379-09e8-40bf-be64-24cabc0e0f9b

The open-access MAF lists 90 somatic variants for this specimen: 60 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Intron 4, 3'UTR 3, Nonsense Mutation 2, RNA 2, 3'Flank 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.2159A>T p.Y720F | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51945221; called by muse, mutect2
- APOE | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as COSV52985427; called by muse, mutect2
- CNTN2 | c.1957T>A p.W653R | Missense Mutation (SNP) | VAF 21/353 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59351665; called by muse, mutect2
- DGCR6L | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs758568156; called by muse, mutect2
- FAT1 | c.12721A>G p.I4241V | Missense Mutation (SNP) | VAF 31/720 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99072780; called by muse, mutect2
- FMR1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54425002; called by muse, mutect2
- GPR50 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV99506658; called by muse, mutect2
- IGHV1-3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs1333699560; called by muse, mutect2
- KEAP1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 25/706 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV50277303, COSV50652664, COSV99408437; called by muse, mutect2
- LAIR1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 21/636 reads (3%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as COSV100479479, COSV57309163; called by muse, mutect2
- OR6A2 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60264434; called by muse, mutect2
- P3H3 | c.560A>T p.H187L | Missense Mutation (SNP) | VAF 41/814 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51831975; called by muse, mutect2
- PHOSPHO1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 25/586 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1324158564, COSV99865094; called by muse, mutect2
- SEZ6L | c.1786C>A p.P596T | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466004647; called by muse, mutect2
- SLC9A6 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 21/433 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs367724979; ClinVar: likely benign; called by muse, mutect2
- SPTBN5 | c.992C>A p.A331E | Missense Mutation (SNP) | VAF 19/351 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV58019771; called by muse, mutect2
- STPG3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280810271; called by muse, mutect2
- ALDH18A1 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 29/767 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALPK3 | c.3471G>T p.E1157D | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ARX | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 26/931 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BPIFB1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- CAMK2B | c.19T>A p.C7S | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.101); called by muse, mutect2
- CD160 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CD300C | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CHL1 | c.2398G>T p.V800L (on ENST00000397491 / NM_001253387.1; = p.V816L on NM_006614.4) | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- CLUHP11 | n.720-3C>A | Splice Region (SNP) | VAF 18/443 reads (4%) | called by muse, mutect2
- CPEB3 | c.1222A>C p.N408H | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2
- CSMD3 | c.10474G>T p.D3492Y (on ENST00000297405 / NM_001363185.1; = p.D3323Y on NM_052900.3) | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); called by muse, mutect2
- DDX10 | c.1679A>C p.Q560P | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- DGKZ | c.914A>T p.Y305F (on ENST00000454345 / NM_001105540.2; = p.Y116F on NM_003646.4) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.078); called by muse, mutect2
- DOLPP1 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- GABRA3 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 26/585 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GREB1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 17/361 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2
- HDAC4 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 27/918 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2
- KRTAP9-1 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 40/1038 reads (4%) | SIFT tolerated (0.29); called by muse, mutect2
- L1TD1 | c.1325A>T p.Q442L | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- MGAM2 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- MTDH | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 40/846 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MUC16 | c.1618A>G p.S540G | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2
- NOX3 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- OR2A14 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- PCDHGA3 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDE3A | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.187); called by muse, mutect2
- PLEC | c.13168T>C p.S4390P (on ENST00000322810 / NM_201380.4; = p.S4280P on NM_000445.5) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PLXDC2 | c.686G>T p.W229L | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPP1R12B | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF213 | c.5802G>T p.W1934C | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2
- RTL5 | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 20/602 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.108); called by muse, mutect2
- SIGLEC12 | c.1345C>A p.Q449K (on ENST00000291707 / NM_053003.4; = p.Q331K on NM_033329.2) | Missense Mutation (SNP) | VAF 23/569 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SPDYE4 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- SPDYE4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/317 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2
- SRRM2 | c.6395C>T p.S2132L | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ST8SIA2 | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 30/589 reads (5%) | PolyPhen benign (0.007); called by muse, mutect2
- STXBP1 | c.1452C>A p.D484E | Missense Mutation (SNP) | VAF 32/806 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- TANC2 | c.3634A>C p.T1212P | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); called by muse, mutect2
- TPO | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- TPO | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.428); called by muse, mutect2
- UBXN2B | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- ZMYM3 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- ZNF770 | c.1925G>T p.R642I | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ALS2 | c.1054C>T p.L352= | Silent (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- CDON | c.3495C>T p.V1165= | Silent (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- EVC2 | c.2931G>C p.R977= | Silent (SNP) | VAF 37/975 reads (4%) | catalogued as COSV100185688; called by muse, mutect2
- GLRA4 | c.858C>A p.A286= | Silent (SNP) | VAF 44/856 reads (5%) | called by muse, mutect2
- GRIPAP1 | c.2274G>T p.R758= | Silent (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- IGHV1-2 | c.169C>A p.R57= | Silent (SNP) | VAF 42/1014 reads (4%) | catalogued as rs368557039; called by muse, mutect2
- INA | c.963G>A p.A321= | Silent (SNP) | VAF 17/386 reads (4%) | catalogued as COSV63976140; called by muse, mutect2
- KIR2DS4 | c.237G>T p.G79= | Silent (SNP) | VAF 32/391 reads (8%) | called by muse, mutect2
- LHCGR | c.921A>T p.T307= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs1416293422; called by muse, mutect2
- MEI1 | c.921G>T p.A307= | Silent (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- NRXN1 | c.4179G>T p.V1393= | Silent (SNP) | VAF 16/465 reads (3%) | catalogued as COSV100640191; called by muse, mutect2
- NUB1 | c.684G>T p.V228= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- NXPE2 | c.501G>T p.V167= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- PRKCG | c.1536C>A p.T512= | Silent (SNP) | VAF 22/540 reads (4%) | called by muse, mutect2
- PROX1 | c.1323G>A p.L441= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- SCN8A | c.5445G>A p.L1815= | Silent (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- SLC35A2 | c.1068C>A p.S356= | Silent (SNP) | VAF 18/502 reads (4%) | catalogued as COSV54430255; called by muse, mutect2
- STS | c.1041C>T p.S347= | Silent (SNP) | VAF 14/364 reads (4%) | called by muse, mutect2
- TCN1 | c.585G>T p.L195= | Silent (SNP) | VAF 41/783 reads (5%) | called by muse, mutect2
- TPO | c.723C>A p.I241= | Silent (SNP) | VAF 34/700 reads (5%) | catalogued as COSV61102106; called by muse, mutect2
- AL163974.1 | chr14:100587278 C>T | 3'Flank (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1038+2599G>A | Intron (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- DCD | c.290-159G>T | Intron (SNP) | VAF 25/462 reads (5%) | called by muse, mutect2
- IGFN1 | c.1242-465G>A | Intron (SNP) | VAF 21/364 reads (6%) | catalogued as rs866393822, COSV55170790; called by muse, mutect2
- KRT17P1 | n.1267T>A | RNA (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- PGA5 | c.657-56G>A | Intron (SNP) | VAF 50/1156 reads (4%) | called by muse, mutect2
- SNURFL | n.299C>G | RNA (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- TAZ | c.*486C>T | 3'UTR (SNP) | VAF 20/389 reads (5%) | called by muse, mutect2
- U2AF1L4 | c.*87C>T | 3'UTR (SNP) | VAF 26/403 reads (6%) | catalogued as COSV99495129; called by muse, mutect2
- XIAP | c.*6097C>G | 3'UTR (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
